Somatic mutation profile of tumor specimen TARGET-20-PASUVD-09A (aliquot TARGET-20-PASUVD-09A-01D) from TARGET case TARGET-20-PASUVD, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.2 years (6,299 days).
Specimen TARGET-20-PASUVD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1fb9ca11-0ab6-4ebc-97b1-552aee4bd695.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASUVD-14A (Bone Marrow Normal), aliquot TARGET-20-PASUVD-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/891c35d3-151f-4305-b89b-353940073293

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSF3R | c.1853C>T p.T618I | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs796065343, COSV58963463; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2
- ASXL2 | c.1804C>T p.Q602* | Nonsense Mutation (SNP) | VAF 56/188 reads (30%) | called by muse, mutect2, varscan2
- RAD21 | c.374_374+21delinsGCCAGC p.X125_splice | Splice Site (DEL) | VAF 58/155 reads (37%) | called by pindel, varscan2*
